Somatic mutation profile of tumor specimen MMRF_1774_1_BM_CD138pos (aliquot MMRF_1774_1_BM_CD138pos_T2_KBS5U_K11910) from MMRF case MMRF_1774, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,925 days).
Specimen MMRF_1774_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14295235-d381-4c16-b3c2-40de62e27bc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1774_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1774_1_PB_Whole_C7_KBS5U_K11916; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/584a4de2-b73f-48fb-a662-896c15b28a90

The open-access MAF lists 101 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 27, Intron 14, Silent 9, 5'UTR 4, 3'Flank 2, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.398T>C p.M133T | Missense Mutation (SNP) | VAF 54/56 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs28934873, CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMOTL1 | c.2166T>A p.N722K | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV58569440; called by muse, mutect2, varscan2
- ARL6IP4 | c.1055C>T p.A352V (on ENST00000315580 / NM_018694.3; = p.A333V on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs777152479; called by muse, mutect2, varscan2
- BCL9L | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs141797896; called by muse, mutect2, varscan2
- GNAS | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 119/222 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs372938101; called by muse, mutect2, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- KCNU1 | c.1703G>T p.C568F | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as rs201035683; called by muse, mutect2
- KLHL28 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100753133; called by muse, mutect2, varscan2
- KLK11 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs145388450; called by muse, mutect2, varscan2
- NME9 | c.719A>C p.D240A (on ENST00000333911 / NM_001349024.2; = p.D179A on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV58618621; called by muse, mutect2, varscan2
- OR10W1 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.828); catalogued as COSV67720412; called by muse, mutect2, varscan2
- OR5I1 | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV56885629; called by muse, mutect2, varscan2
- PCDH11X | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774847953, COSV53472278; called by muse, mutect2, varscan2
- RABEPK | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV99413208; called by muse, mutect2
- SPTA1 | c.4708G>A p.A1570T | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as rs778626016, COSV63748300; called by muse, mutect2
- CHFR | c.911G>C p.C304S (on ENST00000432561 / NM_001161345.1; = p.C263S on NM_018223.2) | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLASP2 | c.1985A>C p.K662T | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CLOCK | c.870T>A p.D290E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DBX2 | c.891A>T p.E297D | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.212); called by muse, mutect2
- DCDC1 | c.592-4C>T | Splice Region (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- DNAH5 | c.1722A>T p.K574N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- FASTKD5 | c.250T>A p.S84T | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FHOD1 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 90/538 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- GID4 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GUF1 | c.930_934del p.H311Ifs*18 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- H1-5 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- HNRNPUL2 | c.538+2T>C p.X180_splice | Splice Site (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.214A>C p.I72L | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, varscan2
- IGLV7-43 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IL23R | c.1861T>C p.F621L | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCNH2 | c.3194A>G p.Q1065R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCARE | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2
- PCDHGC4 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PEX11A | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PLCL2 | c.2563G>T p.G855C (on ENST00000615277 / NM_001144382.2; = p.G729C on NM_015184.5) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTCD1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SIX1 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.63); called by muse, mutect2
- SLC25A12 | c.1992T>G p.S664R | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STRA6 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TCF25 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 19/19 reads (100%) | called by muse, mutect2, varscan2
- TP53I11 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- TRAF2 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIP4 | c.823A>C p.T275P | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF737 | c.195G>T p.M65I | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IFNA2 | c.566G>A p.*189= | Silent (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- KRT1 | c.1575C>T p.Y525= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs780981259; called by muse, mutect2, varscan2
- LRP1B | c.5046C>G p.G1682= | Silent (SNP) | VAF 21/270 reads (8%) | catalogued as COSV104431910; called by muse, mutect2
- MGAM2 | c.4260T>C p.S1420= | Silent (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- MTOR | c.2289T>C p.N763= | Silent (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- NTN4 | c.1212C>T p.V404= | Silent (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- TAF1C | c.57G>C p.L19= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs370093677; called by muse, mutect2, varscan2
- TEX10 | c.396A>G p.E132= | Silent (SNP) | VAF 25/221 reads (11%) | called by muse, mutect2, varscan2
- TRIML2 | c.1044C>G p.T348= | Silent (SNP) | VAF 151/281 reads (54%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.3935-93A>T | Intron (SNP) | VAF 106/246 reads (43%) | called by muse, varscan2
- APC | c.-59T>C | 5'UTR (SNP) | VAF 23/105 reads (22%) | catalogued as rs1554060243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN1 | c.*1750T>C | 3'UTR (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- AZIN2 | c.-72-53G>C | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs1358778269; called by muse, varscan2
- BMP3 | c.*400G>A | 3'UTR (SNP) | VAF 12/79 reads (15%) | catalogued as rs1018817092; called by muse, mutect2, varscan2
- BTBD11 | c.1491-336A>T | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- CLEC1B | chr12:9991575 G>A | 3'Flank (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*1622dup | 3'UTR (INS) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- DCAF4L2 | c.*792T>G | 3'UTR (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- DCHS2 | n.4076A>T | RNA (SNP) | VAF 66/138 reads (48%) | called by muse, mutect2, varscan2
- DTX1 | c.-448A>G | 5'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- ELF2 | c.239-10875_239-10874insCCTGCCCCTGCCGCC | Intron (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- EMX1 | c.521-302C>T | Intron (SNP) | VAF 46/105 reads (44%) | catalogued as rs1408523427; called by muse, mutect2, varscan2
- EXOC5 | c.*4473A>C | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- FLRT3 | c.*1342A>C | 3'UTR (SNP) | VAF 62/122 reads (51%) | called by muse, mutect2, varscan2
- HPGD | c.*390A>C | 3'UTR (SNP) | VAF 28/47 reads (60%) | catalogued as rs571172747; called by muse, mutect2, varscan2
- HYOU1 | c.*941G>C | 3'UTR (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- IFIT5 | c.*1973G>A | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- LDB3 | c.896+6772T>A | Intron (SNP) | VAF 53/326 reads (16%) | called by muse, mutect2, varscan2
- LEF1 | c.214-1111G>C | Intron (SNP) | VAF 23/116 reads (20%) | catalogued as rs755342278, COSV54466857; called by muse, mutect2, varscan2
- LIN28B | c.*1801T>G | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- NAV1 | c.*6152A>G | 3'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- NAV1 | c.*6548C>G | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- NR4A1 | c.-141G>A | 5'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- PARVB | c.712+365G>A | Intron (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- PCDH17 | c.*562T>G | 3'UTR (SNP) | VAF 24/28 reads (86%) | called by muse, mutect2, varscan2
- PLA2G2F | c.*1840C>G | 3'UTR (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- PPP2R5D | c.*575C>T | 3'UTR (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- PRRC2C | c.*1647G>C | 3'UTR (SNP) | VAF 57/158 reads (36%) | called by muse, mutect2, varscan2
- PRSS53 | c.58+33C>T | Intron (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- RAB21 | c.*4673T>C | 3'UTR (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2
- RASA3 | c.*334C>T | 3'UTR (SNP) | VAF 26/69 reads (38%) | catalogued as rs991169964; called by muse, mutect2, varscan2
- RYR1 | c.10440+93G>A | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs142223496; called by muse, mutect2, varscan2
- SEC31A | c.1549-36C>G | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- SEMA3E | c.-168T>A | 5'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs1340789320; called by muse, mutect2
- SMARCB1 | chr22:23835116 C>T | 3'Flank (SNP) | VAF 46/98 reads (47%) | catalogued as rs1223080074; called by muse, mutect2, varscan2
- SMIM7 | c.*150+657C>A | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- SMIM7 | c.*150+538C>A | Intron (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
- SUN1 | c.*556G>C | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- TAB3 | c.*1740A>C | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- TEF | c.*2526A>T | 3'UTR (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- TENM2 | c.503-120889T>A | Intron (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- TFEC | c.*3156A>T | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.*1323T>C | 3'UTR (SNP) | VAF 27/59 reads (46%) | catalogued as rs1272086851; called by muse, mutect2, varscan2
- TMEM132B | c.*1899A>T | 3'UTR (SNP) | VAF 47/94 reads (50%) | catalogued as rs536929844; called by muse, mutect2, varscan2
- VSTM2A | c.*26A>G | 3'UTR (SNP) | VAF 28/244 reads (11%) | called by muse, mutect2, varscan2
- YY2 | c.*394G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as rs1484404104; called by muse, mutect2
- ZBTB39 | c.*3763A>G | 3'UTR (SNP) | VAF 41/88 reads (47%) | catalogued as rs527989990; called by muse, mutect2, varscan2
